Somatic mutation profile of tumor specimen 0DG87P from CCDI case PBBSTU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Desmoplastic nodular medulloblastoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 0.8 years (286 days).
Specimen 0DG87P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed079a51-1019-4e05-bc91-149bec1cbac0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG84F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67f68d0b-b99c-41aa-8b7c-026707f30398

The open-access MAF lists 103 somatic variants for this specimen: 65 protein-altering or splice-affecting, 26 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 26, Frame Shift Del 7, Intron 6, Nonsense Mutation 5, 3'UTR 2, Frame Shift Ins 2, 5'UTR 2, 5'Flank 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 394/925 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTCH1 | c.290del p.N97Tfs*20 | Frame Shift Del (DEL) | VAF 617/695 reads (89%) | catalogued as rs1554708751, CD066395, CX962597; ClinVar: pathogenic; called by mutect2, varscan2
- ABHD8 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 156/382 reads (41%) | catalogued as COSV99395437; called by muse, mutect2, varscan2
- ADAP1 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as rs940331251; called by muse, mutect2
- ADTRP | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 429/1011 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as COSV57642055; called by muse, mutect2, varscan2
- ALPK2 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 151/685 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs184186856, COSV100864540; called by muse, mutect2, varscan2
- ATP1A4 | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 331/731 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs141493998; called by muse, mutect2, varscan2
- BLNK | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 280/741 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs370090701; called by muse, mutect2, varscan2
- C12orf43 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 279/703 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1436788426; called by muse, mutect2, varscan2
- C5orf24 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 56/1162 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs779130296; called by muse, mutect2
- CCDC88C | c.2611G>A p.A871T | Missense Mutation (SNP) | VAF 103/241 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs752834239, COSV66236062; called by muse, mutect2, varscan2
- CGN | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 260/641 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs368607138; called by muse, mutect2, varscan2
- COL11A2 | c.1876G>A p.V626I (on ENST00000341947 / NM_080680.3; = p.V519I on NM_080679.2) | Missense Mutation (SNP) | VAF 130/363 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.251); catalogued as rs755719124; called by muse, mutect2, varscan2
- CPLX2 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 38/588 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs370394171, COSV100853180; called by muse, mutect2
- CRYGD | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 51/939 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs564197072, COSV100006116; ClinVar: benign; called by muse, mutect2
- CSMD1 | c.5507C>T p.T1836M (on ENST00000520002; = p.T1835M on NM_033225.6) | Missense Mutation (SNP) | VAF 489/1259 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs374772217, COSV59288354; called by muse, mutect2, varscan2
- CYFIP2 | c.3458G>A p.R1153Q (on ENST00000616178 / NM_001291722.2; = p.R1128Q on NM_014376.4) | Missense Mutation (SNP) | VAF 209/549 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs768520032; called by muse, mutect2, varscan2
- CYHR1 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 216/461 reads (47%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.948); catalogued as COSV71324724; called by muse, mutect2, varscan2
- CYP26A1 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 301/719 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs754813478; called by muse, mutect2, varscan2
- DNAH2 | c.12994C>T p.R4332W | Missense Mutation (SNP) | VAF 148/348 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV66724973; called by muse, mutect2, varscan2
- DOCK6 | c.3479G>A p.R1160H | Missense Mutation (SNP) | VAF 165/407 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs778082263; called by muse, mutect2, varscan2
- DSG4 | c.2443G>A p.V815I | Missense Mutation (SNP) | VAF 477/1145 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.821); catalogued as rs369634548; called by muse, mutect2, varscan2
- EDRF1 | c.1010G>A p.R337H (on ENST00000356792 / NM_001202438.2; = p.R303H on NM_015608.2) | Missense Mutation (SNP) | VAF 33/1142 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV100524173; called by muse, mutect2
- EXTL3 | c.2626C>T p.R876W | Missense Mutation (SNP) | VAF 34/760 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489070779, COSV55038699; called by muse, mutect2
- KIF26A | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 99/238 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as rs375444859; called by muse, mutect2, varscan2
- KMT2D | c.8200C>T p.R2734* | Nonsense Mutation (SNP) | VAF 187/418 reads (45%) | catalogued as CM111916, COSV56408439; called by muse, mutect2, varscan2
- KMT2D | c.4843C>T p.R1615* | Nonsense Mutation (SNP) | VAF 256/596 reads (43%) | catalogued as CM105487, COSV56420226; called by muse, mutect2, varscan2
- KRTAP10-1 | c.338C>T p.T113I | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1555916926; called by muse, mutect2, varscan2
- LRRC15 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 198/480 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750347638, COSV61651611; called by muse, mutect2, varscan2
- MCM2 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 154/328 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as rs758068207, COSV54034438; called by muse, mutect2, varscan2
- MYBL2 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 205/460 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as rs773951994; called by muse, mutect2, varscan2
- PDE9A | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 40/694 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs748749285, COSV52332989; called by muse, mutect2
- PIBF1 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 495/1146 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs763324526; called by muse, mutect2, varscan2
- PLD6 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 38/483 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs867037481; called by muse, mutect2
- PLEKHG5 | c.537C>G p.Y179* (on ENST00000400915 / NM_001042663.3; = p.Y142* on NM_020631.6) | Nonsense Mutation (SNP) | VAF 16/332 reads (5%) | catalogued as COSV61700731; called by muse, mutect2
- PLEKHM2 | c.2939C>T p.T980M | Missense Mutation (SNP) | VAF 241/594 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs571532775; called by muse, mutect2, varscan2
- PREX1 | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 110/650 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs568035687, COSV100906901, COSV64251564; called by muse, mutect2, varscan2
- RBAK | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 362/888 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761815000; called by muse, mutect2, varscan2
- RTTN | c.5744del p.K1915Rfs*9 | Frame Shift Del (DEL) | VAF 429/944 reads (45%) | catalogued as rs756606313; called by mutect2, varscan2
- SFXN1 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 163/318 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs769920329, COSV58495202; called by muse, mutect2, varscan2
- SLC11A2 | c.833G>A p.R278H (on ENST00000394904 / NM_001379455.1; = p.R249H on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/602 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs770229023, COSV50371218; called by muse, mutect2
- SUPT20HL1 | c.1546G>C p.A516P | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs866999802; called by mutect2, varscan2
- TBC1D4 | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 24/906 reads (3%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100884846; called by muse, mutect2
- TOPAZ1 | c.1893del p.A632Lfs*5 | Frame Shift Del (DEL) | VAF 436/1005 reads (43%) | catalogued as rs753884819, COSV59073348; called by mutect2, varscan2
- TTN | c.7031del p.K2344Rfs*6 (on ENST00000591111; = p.K2298Rfs*6 on NM_003319.4) | Frame Shift Del (DEL) | VAF 374/926 reads (40%) | catalogued as COSV100622884; called by mutect2, varscan2
- UBP1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 461/1205 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs760848453; called by muse, mutect2, varscan2
- XIRP2 | c.1537dup p.D513Gfs*10 (on ENST00000628543; = p.D688Gfs*10 on NM_152381.6) | Frame Shift Ins (INS) | VAF 235/552 reads (43%) | catalogued as rs745648385; called by mutect2, varscan2
- ZZEF1 | c.7558C>T p.R2520W | Missense Mutation (SNP) | VAF 57/1120 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs767129847, COSV101068246; called by muse, mutect2
- ADAMTSL2 | c.2687C>A p.P896H | Missense Mutation (SNP) | VAF 16/455 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BLNK | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 34/805 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- BPTF | c.3259dup p.I1087Nfs*6 | Frame Shift Ins (INS) | VAF 368/1016 reads (36%) | called by mutect2, varscan2
- CHRM2 | c.1078A>G p.I360V | Missense Mutation (SNP) | VAF 447/1054 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHTOP | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 290/688 reads (42%) | called by muse, varscan2
- DACT2 | c.514G>T p.G172W | Missense Mutation (SNP) | VAF 187/402 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ERMAP | c.131del p.G44Afs*20 | Frame Shift Del (DEL) | VAF 170/442 reads (38%) | called by mutect2, varscan2
- FBXL17 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 66/1303 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2
- MFHAS1 | c.163del p.Q55Sfs*14 | Frame Shift Del (DEL) | VAF 158/388 reads (41%) | called by mutect2, varscan2
- NEB | c.10991A>G p.Q3664R | Missense Mutation (SNP) | VAF 50/881 reads (6%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.702); called by muse, mutect2
- NFAT5 | c.3204G>T p.Q1068H | Missense Mutation (SNP) | VAF 78/1034 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- PLCB3 | c.2752del p.R918Afs*95 | Frame Shift Del (DEL) | VAF 142/311 reads (46%) | called by mutect2, varscan2
- SPTBN1 | c.5074G>T p.G1692C | Missense Mutation (SNP) | VAF 348/832 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TNRC6A | n.277-2A>G | Splice Site (SNP) | VAF 52/111 reads (47%) | called by muse, mutect2, varscan2
- TOR4A | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 117/272 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZBTB4 | c.1926G>T p.E642D | Missense Mutation (SNP) | VAF 241/471 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF775 | c.628C>A p.Q210K | Missense Mutation (SNP) | VAF 183/386 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ABAT | c.588G>A p.T196= | Silent (SNP) | VAF 160/377 reads (42%) | catalogued as rs754582322; called by muse, mutect2, varscan2
- ABHD14A | c.468G>A p.A156= | Silent (SNP) | VAF 228/499 reads (46%) | catalogued as rs368171899; called by muse, mutect2, varscan2
- ADAMTS16 | c.1806C>T p.C602= | Silent (SNP) | VAF 237/533 reads (44%) | catalogued as rs199944943, COSV57000186; called by muse, mutect2, varscan2
- ADCY9 | c.3450C>T p.D1150= | Silent (SNP) | VAF 191/427 reads (45%) | catalogued as rs758359636, COSV53576682; called by muse, mutect2, varscan2
- ANKRD20A1 | c.501T>C p.N167= | Silent (SNP) | VAF 152/1103 reads (14%) | called by muse, mutect2, varscan2
- CATSPERG | c.2817C>T p.S939= | Silent (SNP) | VAF 252/558 reads (45%) | catalogued as rs752358911; called by muse, mutect2, varscan2
- CFAP69 | c.1323C>T p.C441= | Silent (SNP) | VAF 386/950 reads (41%) | called by muse, varscan2
- CSN3 | c.321G>T p.V107= | Silent (SNP) | VAF 371/811 reads (46%) | called by mutect2, varscan2
- EFCAB6 | c.1647C>T p.C549= | Silent (SNP) | VAF 40/664 reads (6%) | called by muse, mutect2
- F13A1 | c.1719G>A p.T573= | Silent (SNP) | VAF 217/477 reads (45%) | catalogued as rs559216222; called by muse, mutect2, varscan2
- FBXL15 | c.244C>T p.L82= | Silent (SNP) | VAF 141/329 reads (43%) | called by muse, mutect2, varscan2
- GAS2L2 | c.1443G>A p.A481= | Silent (SNP) | VAF 84/190 reads (44%) | catalogued as rs782510431; called by muse, mutect2, varscan2
- GPR61 | c.96G>A p.P32= | Silent (SNP) | VAF 211/597 reads (35%) | catalogued as rs371039936; called by muse, mutect2, varscan2
- IGSF9B | c.1731G>A p.A577= | Silent (SNP) | VAF 270/561 reads (48%) | catalogued as rs372458520; called by muse, mutect2, varscan2
- KATNB1 | c.1104C>T p.D368= | Silent (SNP) | VAF 159/396 reads (40%) | catalogued as rs201625277, COSV101109304; called by muse, mutect2, varscan2
- KIAA1549L | c.5037C>T p.H1679= (on ENST00000321505; = p.H1976= on NM_012194.3) | Silent (SNP) | VAF 341/807 reads (42%) | catalogued as rs755385142, COSV58583743; called by muse, mutect2, varscan2
- LAMB4 | c.1581C>T p.C527= | Silent (SNP) | VAF 139/782 reads (18%) | called by muse, mutect2, varscan2
- LMBR1L | c.1023C>T p.G341= | Silent (SNP) | VAF 22/366 reads (6%) | called by muse, mutect2
- MAP3K10 | c.2442C>T p.H814= | Silent (SNP) | VAF 97/266 reads (36%) | catalogued as rs371152583; called by muse, mutect2, varscan2
- MTMR2 | c.156T>C p.T52= | Silent (SNP) | VAF 45/1590 reads (3%) | called by muse, mutect2
- NOTCH3 | c.6111C>T p.H2037= | Silent (SNP) | VAF 95/234 reads (41%) | catalogued as rs764620593, COSV54650154; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PALLD | c.2112C>T p.Y704= | Silent (SNP) | VAF 409/969 reads (42%) | catalogued as rs372414187; ClinVar: likely benign; called by muse, mutect2, varscan2
- PASK | c.2811C>T p.R937= | Silent (SNP) | VAF 281/584 reads (48%) | catalogued as rs200236190; called by muse, mutect2, varscan2
- RYR1 | c.8580C>T p.P2860= | Silent (SNP) | VAF 212/495 reads (43%) | catalogued as rs749495512, COSV62114847; called by muse, mutect2, varscan2
- URB2 | c.1218G>A p.P406= | Silent (SNP) | VAF 316/803 reads (39%) | called by muse, mutect2, varscan2
- ZDHHC3 | c.516C>T p.F172= | Silent (SNP) | VAF 299/700 reads (43%) | catalogued as COSV56101060; called by muse, mutect2, varscan2
- AC011525.1 | n.894G>A | RNA (SNP) | VAF 187/446 reads (42%) | catalogued as rs763496336; called by muse, mutect2, varscan2
- CCDC120 | c.957-56C>T | Intron (SNP) | VAF 8/92 reads (9%) | catalogued as rs781961010; called by muse, mutect2
- DPYSL5 | c.*83G>T | 3'UTR (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- FAM3B | c.20-70del | Intron (DEL) | VAF 41/83 reads (49%) | catalogued as rs1443925521; called by mutect2, varscan2
- GRAMD1A | c.-57_-53dup | 5'UTR (INS) | VAF 67/149 reads (45%) | catalogued as rs959187219; called by mutect2, varscan2
- IL36B | c.261+992G>T | Intron (SNP) | VAF 330/792 reads (42%) | catalogued as COSV99383039; called by muse, mutect2, varscan2
- MFAP2 | c.286+37C>T | Intron (SNP) | VAF 102/266 reads (38%) | catalogued as rs761350384; called by muse, mutect2, varscan2
- NUBP2 | c.135+47C>T | Intron (SNP) | VAF 96/187 reads (51%) | called by muse, mutect2, varscan2
- OIT3 | chr10:72893711 del A | 5'Flank (DEL) | VAF 38/82 reads (46%) | catalogued as rs1161219246, COSV61825112; called by mutect2, varscan2
- PSMD1 | c.-51C>T | 5'UTR (SNP) | VAF 111/308 reads (36%) | catalogued as rs1318075346; called by muse, mutect2, varscan2
- SLC17A9 | c.59+374A>G | Intron (SNP) | VAF 212/491 reads (43%) | called by muse, mutect2, varscan2
- TBL3 | c.*1618del | 3'UTR (DEL) | VAF 51/112 reads (46%) | catalogued as rs552247687; called by mutect2, varscan2
